Somatic mutation profile of tumor specimen BA2198D (aliquot aq-BA2198D) from BEATAML1.0 case 2338, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,455 days).
Specimen BA2198D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05faabc7-1781-4f95-ba0f-fdc8fd1f0bf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2495D (Solid Tissue Normal), aliquot aq-BA2495D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2883dbe0-6f24-4730-a1ff-8b687547ed3e

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 86/259 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045993, CM071099, COSV59127614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs756690261; called by muse, mutect2, varscan2
- C2CD4C | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs893101476; called by muse, mutect2
- CSF3R | c.2256T>A p.Y752* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58971230; called by muse, mutect2
- GPRIN2 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs1555019588; called by mutect2, varscan2
- ITGAE | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1313192748; called by muse, mutect2, varscan2
- KCND3 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1332646922, COSV56175522; called by muse, mutect2, varscan2
- MAPK13 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs759807867, COSV99274972; called by muse, mutect2, varscan2
- SLC35G3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs147490548; called by muse, mutect2, varscan2
- SPTBN1 | c.2191C>A p.Q731K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100443445; called by muse, mutect2
- VWA2 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV53910133; called by muse, mutect2
- ACAN | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ANGPTL1 | c.516C>G p.Y172* | Nonsense Mutation (SNP) | VAF 72/170 reads (42%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.489T>G p.C163W | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DGKB | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPAP1 | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.422); called by muse, mutect2
- PLXNA2 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- PPP1R12A | c.2723C>G p.S908C | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SLC35B4 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQCA1 | c.1617C>G p.P539= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- CNGA3 | c.215+405G>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs1189901380; called by muse, mutect2
- SH2B1 | c.1898-190C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs370302573; called by muse, varscan2
